Gene-level copy-number profile of tumor specimen C3N-03877-01 (profiled together with C3N-03877-02) from CPTAC case C3N-03877, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.9 years (19,674 days).
Specimen C3N-03877-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4da8cc71-e5eb-491f-99b7-1a2d96463d90.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03877-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/74062516-6e08-4749-8510-be76a5469c75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 23,453; copy number 2: 30,657; copy number 3: 4,312; copy number 4: 110; copy number 5: 1; copy number 6: 52; copy number 7: 58; copy number 8: 46; copy number 9: 21; copy number 10: 38; copy number 13: 12; copy number 17: 80.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–2): RNU6-904P, RPS16P3.
- chr3:1,905,651–1,906,125, 1 gene: RPL21P17.
- chr4:60,922,619–62,078,335, 7 genes (within-gene range 0–1): MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA.
- chr9:21,802,636–25,089,151, 32 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–1): BNIP3P22, AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 308 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–175,810,548, 159 genes, copy number 5–17 (broad region; genes not listed).
- chr3:181,699,608–181,699,883, 1 gene, copy number 7 (within-gene range 2–7): AC117415.1.
- chr3:181,847,526–184,060,673, 49 genes, copy number 7–10: AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D, HTR3C.
- chr3:188,153,284–188,890,671, 1 gene, copy number 8 (within-gene range 2–8): LPP.
- chr3:188,562,238–188,688,866, 2 genes, copy number 8: LPP-AS1, MIR28.
- chr3:188,947,214–189,325,304, 1 gene, copy number 8 (within-gene range 2–8): TPRG1.
- chr3:189,238,686–189,240,594, 1 gene, copy number 8: TPRG1-AS2.
- chr3:192,796,815–194,832,592, 50 genes, copy number 7–9: MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037, LINC02048, LINC00887, AC117469.1, CPN2, LRRC15, GP5, ATP13A3, AC108676.2, LINC00884, AC108676.1, RNU6-1101P, RPL23AP93, TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2.
- chr14:50,329,404–50,831,162, 14 genes, copy number 10 (within-gene range 4–10): CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1, ZFP64P1, NIN, AL606834.2.
- chr14:51,344,914–52,637,713, 30 genes, copy number 6 (within-gene range 4–6): AL358332.1, LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C.

Autosomal genes at a single copy (total copy number 1): 20,600. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
